Gene-level copy-number profile of tumor specimen HTMCP-03-06-02424-01A from CGCI case HTMCP-03-06-02424, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 35.8 years (13,085 days).
Specimen HTMCP-03-06-02424-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8ed78199-6ca3-46cc-99cb-81d69c5670f3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02424-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/0f9c7cd0-9666-4dfc-bbbb-dfd356ab2fa0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 2; copy number 2: 4,042; copy number 3: 465; copy number 4: 46,714; copy number 5: 382; copy number 6: 5,907; copy number 7: 96; copy number 8: 224; copy number 9: 30; copy number 10: 50; copy number 11: 53; copy number 12: 187; copy number 13: 53; copy number 14: 43; copy number 15: 24; copy number 16: 97; copy number 17: 4.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:214,344,172–214,357,615, 1 gene (within-gene range 0–4): AL929236.1.
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–4): RNU6-904P, RPS16P3.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 541 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:72,129,238–83,219,105, 174 genes, copy number 12–15 (broad region; genes not listed).
- chr2:85,657,314–85,668,741, 1 gene, copy number 12: SFTPB.
- chr2:85,751,344–87,825,952, 56 genes, copy number 11–15: ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5, ST3GAL5-AS1, AC012511.1, POLR1A, PTCD3, SNORD94, IMMT, Y_RNA, MIR4779, AC009309.1, MRPL35, REEP1, U8, AC009408.1, KDM3A, CHMP3, RNF103-CHMP3, RNU6-640P, AC015971.1, RNF103, RMND5A, CD8A, CD8B, ANAPC1P1, AC111200.1, RGPD1, WBP1P1, NDUFB4P5, PLGLB1, ANAPC1P2, ANAPC1P2, AC092651.1, ANAPC1P3, AC083899.1, MIR4771-1, CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943, CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5, ANAPC1P4, PLGLB2, RGPD2, MTATP8P2.
- chr2:88,027,205–90,235,370, 102 genes, copy number 11–12 (broad region; genes not listed).
- chr2:91,578,478–91,621,421, 3 genes, copy number 9 (within-gene range 4–9): AC233266.1, AC233266.2, AC116050.1.
- chr2:173,871,653–174,502,312, 20 genes, copy number 13–17: RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24, OLA1, AC013467.1, RN7SL65P, Y_RNA, LRRC2P1, HNRNPA1P39, LINC01305, AC018470.1, SP9, CIR1, SCRN3, GPR155, AC010894.1, RPA3P1.
- chr2:176,077,472–180,007,297, 97 genes, copy number 16 (broad region; genes not listed).
- chr2:180,692,104–180,916,939, 2 genes, copy number 15 (within-gene range 8–15): SCHLAP1, AC104820.1.
- chr2:188,598,791–190,569,776, 35 genes, copy number 10–12: AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179.
- chr8:33,604,856–34,039,104, 1 gene, copy number 12 (within-gene range 2–12): AF279873.3.
- chr8:33,859,480–34,346,731, 7 genes, copy number 9–12: AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3.
- chr18:2,537,525–2,805,017, 10 genes, copy number 9 (within-gene range 8–9): METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1.
- chr18:3,394,889–5,317,664, 33 genes, copy number 9–13: IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
